Somatic mutation profile of tumor specimen 0DA6QR from CCDI case PBBIKD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,365 days).
Specimen 0DA6QR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98662f8c-0b93-4603-ba83-427ce6bf58ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA6QG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43601c0b-aa77-4497-a168-fa914b220d03

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 4, Intron 4, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO31 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61149287; called by muse, mutect2, varscan2
- FERMT3 | c.1313G>A p.R438Q (on ENST00000279227 / NM_178443.3; = p.R434Q on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767054440, COSV54177003; called by muse, mutect2, varscan2
- FSIP2 | c.19546G>T p.E6516* | Nonsense Mutation (SNP) | VAF 27/1084 reads (2%) | catalogued as COSV58078076; called by muse, mutect2
- GBP5 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 99/934 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.309); catalogued as rs1034629134; called by muse, mutect2, varscan2
- MKS1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 466/1283 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100439580, COSV58304856; called by muse, mutect2, varscan2
- NHS | c.1791C>A p.S597R | Missense Mutation (SNP) | VAF 48/1268 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV66275823; called by muse, mutect2
- PBLD | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs750680281, COSV53266398; called by muse, mutect2, varscan2
- SGSM1 | c.3265G>A p.V1089I (on ENST00000400359 / NM_001039948.4; = p.V1028I on NM_133454.3) | Missense Mutation (SNP) | VAF 452/1066 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778440333, COSV68509313; called by muse, mutect2, varscan2
- TNFAIP1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 24/675 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.061); catalogued as rs781938125; called by muse, mutect2
- TNXB | c.7655G>A p.R2552H (on ENST00000647633; = p.R2305H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/1356 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as rs763647914, COSV100926587; called by muse, mutect2
- WDR6 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as rs1424039660; called by muse, mutect2, varscan2
- ABCA12 | c.4630A>G p.S1544G (on ENST00000272895 / NM_173076.3; = p.S1226G on NM_015657.3) | Missense Mutation (SNP) | VAF 349/850 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- AKR1B15 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 236/1322 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- FGFR1OP2 | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 78/884 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- LUZP2 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 50/1406 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- LY6G6C | c.261T>A p.Y87* | Nonsense Mutation (SNP) | VAF 112/485 reads (23%) | called by muse, mutect2, varscan2
- MAGI2 | c.3953C>T p.A1318V | Missense Mutation (SNP) | VAF 25/891 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- MED24 | c.2053A>G p.I685V | Missense Mutation (SNP) | VAF 66/583 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MOCS1 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 94/647 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OTUD7B | c.2491G>T p.E831* | Nonsense Mutation (SNP) | VAF 64/1438 reads (4%) | called by muse, mutect2
- RBM19 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 26/958 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR1 | c.4738C>A p.Q1580K | Missense Mutation (SNP) | VAF 171/648 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R16 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 119/849 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- UVSSA | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 144/834 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF630 | c.656G>C p.C219S | Missense Mutation (SNP) | VAF 88/1052 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.029); called by muse, mutect2
- FBXO31 | c.225G>A p.L75= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs1446343639; called by muse, mutect2, varscan2
- HSPG2 | c.7332G>A p.S2444= | Silent (SNP) | VAF 46/1084 reads (4%) | catalogued as rs149487261; called by muse, mutect2
- MAOA | c.915G>A p.K305= | Silent (SNP) | VAF 30/1111 reads (3%) | called by muse, mutect2
- MEIS2 | c.147G>A p.Q49= (on ENST00000561208 / NM_170675.5; = p.Q36= on NM_002399.3) | Silent (SNP) | VAF 51/423 reads (12%) | catalogued as COSV99576329; called by muse, mutect2, varscan2
- NOBOX | c.468G>T p.G156= | Silent (SNP) | VAF 33/1097 reads (3%) | catalogued as COSV56193432; called by muse, mutect2
- OR5J2 | c.498G>C p.L166= | Silent (SNP) | VAF 36/1099 reads (3%) | called by muse, mutect2
- PCDHB14 | c.2088G>A p.S696= | Silent (SNP) | VAF 10/220 reads (5%) | catalogued as rs541318724, COSV53391324; called by muse, mutect2
- REXO5 | c.957G>C p.L319= | Silent (SNP) | VAF 92/1122 reads (8%) | catalogued as COSV54474941; called by muse, mutect2
- SLX4 | c.4725G>A p.K1575= | Silent (SNP) | VAF 279/667 reads (42%) | called by muse, mutect2, varscan2
- APOL2 | c.*48G>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- CLUL1 | c.1209+38C>T | Intron (SNP) | VAF 18/118 reads (15%) | catalogued as rs202122870; called by muse, mutect2, varscan2
- COL1A1 | c.1002+39G>T | Intron (SNP) | VAF 53/394 reads (13%) | called by muse, mutect2, varscan2
- COL4A1 | c.553-30C>G | Intron (SNP) | VAF 41/409 reads (10%) | catalogued as rs1411709028; called by muse, mutect2, varscan2
- FYTTD1 | c.104-660G>C | Intron (SNP) | VAF 56/822 reads (7%) | called by muse, mutect2
- ZNF556 | c.*68G>A | 3'UTR (SNP) | VAF 15/42 reads (36%) | catalogued as rs954567322; called by muse, mutect2, varscan2
